Somatic mutation profile of tumor specimen TCGA-G3-A25S-01A (aliquot TCGA-G3-A25S-01A-11D-A16V-10) from TCGA case TCGA-G3-A25S, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 64.5 years (23,571 days).
Specimen TCGA-G3-A25S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0d613b2d-0dc8-4112-9c76-c56c280180be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G3-A25S-10A (Blood Derived Normal), aliquot TCGA-G3-A25S-10A-01D-A16V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a04c8ce0-db27-4b61-9f74-793cf2ff899a

The open-access MAF lists 130 somatic variants for this specimen: 101 protein-altering or splice-affecting, 23 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 23, Nonsense Mutation 10, Frame Shift Del 4, Intron 4, Splice Site 3, 3'UTR 2, Frame Shift Ins 2, Translation Start Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRNT1 | c.542_545del p.V181Dfs*18 | Frame Shift Del (DEL) | VAF 23/133 reads (17%) | catalogued as rs769317780; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ADAMTSL3 | c.3179T>C p.L1060S | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV54437657; called by muse, mutect2, varscan2
- ADGRF4 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV51949913; called by muse, mutect2, varscan2
- ADSS2 | c.383T>A p.I128N | Missense Mutation (SNP) | VAF 32/792 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.762); catalogued as COSV63694571; called by muse, mutect2
- AGPAT3 | c.834C>G p.Y278* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as COSV52368005; called by muse, mutect2, varscan2
- ARHGEF17 | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs934073278, COSV55229949; called by muse, mutect2, varscan2
- BSN | c.7903C>T p.R2635C | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762860512, COSV56513493; called by muse, mutect2, varscan2
- CASP4 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs559503139, COSV67744211; called by muse, mutect2, varscan2
- CCDC14 | c.1128T>A p.D376E (on ENST00000488653; = p.D328E on NM_022757.5) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.048); catalogued as rs777809722, COSV59943124; called by muse, mutect2, varscan2
- CD38 | c.631T>C p.S211P | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56888628; called by muse, mutect2, varscan2
- CDK9 | c.725G>T p.S242I | Missense Mutation (SNP) | VAF 44/57 reads (77%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.957); catalogued as COSV64723417; called by muse, mutect2, varscan2
- CDKN1A | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 41/44 reads (93%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV55187201; called by muse, mutect2, varscan2
- CDKN1A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 40/44 reads (91%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.231); catalogued as COSV55187211; called by muse, mutect2, varscan2
- CELF3 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.035); catalogued as rs966059814, COSV51881765; called by muse, mutect2, varscan2
- CHL1 | c.1878G>T p.R626S (on ENST00000397491 / NM_001253387.1; = p.R642S on NM_006614.4) | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs763642714, COSV56587375, COSV56593468, COSV56604988; called by muse, mutect2, varscan2
- CHRM4 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1395969075, COSV59179639, COSV59180060; called by muse, mutect2, varscan2
- CNDP2 | c.1180T>A p.Y394N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60839077; called by muse, mutect2, varscan2
- CNIH2 | c.351T>G p.Y117* | Nonsense Mutation (SNP) | VAF 18/30 reads (60%) | catalogued as COSV61012150; called by muse, mutect2, varscan2
- COL4A2 | c.563A>G p.E188G | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.565); catalogued as COSV64625215; called by muse, mutect2, varscan2
- COL6A6 | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV62018804; called by muse, mutect2, varscan2
- CPN1 | c.1339G>A p.E447K | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV100962607, COSV64941978, COSV64942117; called by muse, mutect2, varscan2
- CRIP3 | c.409G>A p.V137M | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV51482992; called by muse, varscan2
- CRIP3 | c.407A>T p.K136M | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV51485580; called by muse, varscan2
- CRIP3 | c.406A>G p.K136E | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as COSV51485604; called by muse, varscan2
- DHX9 | c.3023A>T p.E1008V | Missense Mutation (SNP) | VAF 76/141 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.665); catalogued as COSV62358359; called by muse, mutect2, varscan2
- DMXL1 | c.3746C>T p.P1249L | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV60705530; called by muse, mutect2, varscan2
- DNAH6 | c.4358G>T p.R1453L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52850725; called by muse, mutect2, varscan2
- DNAJC18 | c.359C>A p.T120K | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV57415114; called by muse, mutect2, varscan2
- DYSF | c.1546C>A p.P516T | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50271828; called by mutect2, varscan2
- ELL2 | c.1745G>T p.G582V | Missense Mutation (SNP) | VAF 77/126 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52981305; called by muse, mutect2, varscan2
- EXOC2 | c.1118G>A p.C373Y | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57861750; called by muse, mutect2, varscan2
- FIGNL1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs781103365, COSV63553237; called by muse, mutect2, varscan2
- FN1 | c.5974+1G>C p.X1992_splice | Splice Site (SNP) | VAF 30/216 reads (14%) | catalogued as rs111852829, COSV60547425; called by muse, varscan2
- FREM2 | c.3574G>T p.E1192* | Nonsense Mutation (SNP) | VAF 43/53 reads (81%) | catalogued as COSV54829835; called by muse, mutect2, varscan2
- FSTL4 | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV54764698, COSV99532598; called by muse, mutect2, varscan2
- GDF5 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV65499598; called by muse, mutect2, varscan2
- GPR63 | c.638T>C p.L213S | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.55); PolyPhen benign (0.097); catalogued as COSV57739749; called by muse, mutect2, varscan2
- GRID2IP | c.1299C>A p.Y433* | Nonsense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV70691838; called by muse, mutect2, varscan2
- INSIG1 | c.596G>A p.G199D | Missense Mutation (SNP) | VAF 40/186 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60919832; called by muse, mutect2, varscan2
- IQGAP1 | c.3149C>T p.T1050M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1388244542, COSV51581899; called by muse, mutect2, varscan2
- KBTBD3 | c.413C>G p.S138C | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.794); catalogued as COSV73241246; called by muse, mutect2, varscan2
- LAMA1 | c.6470A>T p.Y2157F | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.576); catalogued as COSV67532734; called by muse, mutect2, varscan2
- LINGO2 | c.287T>A p.V96E | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58057578; called by muse, mutect2, varscan2
- LUZP4 | c.788A>G p.Q263R | Missense Mutation (SNP) | VAF 57/92 reads (62%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.881); catalogued as COSV64218445; called by muse, mutect2, varscan2
- MALT1 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); catalogued as COSV61934158; called by muse, mutect2, varscan2
- MBD4 | c.997A>T p.I333L | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.014); catalogued as rs994641746, COSV51443973; called by muse, mutect2, varscan2
- MCM7 | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.11); catalogued as COSV57994161; called by muse, mutect2, varscan2
- MUC6 | c.2383G>A p.G795S | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763956171, COSV70135492; called by muse, mutect2, varscan2
- MYLK4 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs796052168, COSV51138552; ClinVar: likely benign; called by muse, mutect2, varscan2
- NBEA | c.8016_8017insC p.D2673Rfs*17 | Frame Shift Ins (INS) | VAF 26/49 reads (53%) | catalogued as COSV100076038; called by mutect2, pindel, varscan2
- NFATC4 | c.1916T>A p.L639Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.856); catalogued as COSV51597066; called by muse, mutect2, varscan2
- NLGN1 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV64324519, COSV64348686; called by muse, mutect2, varscan2
- NLGN1 | c.634C>A p.L212I | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV64324526; called by muse, mutect2, varscan2
- NRIP2 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.792); catalogued as COSV61701163; called by muse, mutect2, varscan2
- NSD2 | c.2699A>G p.H900R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56386944; called by muse, mutect2
- OR2AE1 | c.611T>C p.I204T | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV60389735; called by muse, mutect2, varscan2
- PADI3 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as rs35624745; called by muse, mutect2, varscan2
- PBX1 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63341345; called by muse, mutect2, varscan2
- PCNX2 | c.365A>G p.N122S | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.098); catalogued as COSV50783544; called by muse, mutect2, varscan2
- PDLIM3 | c.298C>G p.R100G (on ENST00000284770 / NM_001257963.1; = p.R267G on NM_014476.6) | Missense Mutation (SNP) | VAF 15/16 reads (94%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV52977959, COSV52981453; called by muse, mutect2, varscan2
- PKHD1 | c.5781A>T p.R1927S | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as rs1278736824, COSV61862476; called by muse, mutect2, varscan2
- PLCB1 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.05); catalogued as COSV62039802; called by muse, mutect2, varscan2
- PLD5 | c.492T>A p.C164* (on ENST00000442594; = p.C102* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 54/510 reads (11%) | catalogued as COSV59134868; called by muse, mutect2, varscan2
- PRL | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.771); catalogued as COSV60591418, COSV60591766; called by muse, mutect2, varscan2
- PTPN6 | c.758A>G p.K253R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV100017277, COSV59683537; called by mutect2, varscan2
- RAB31 | c.493C>A p.R165S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV71261208; called by muse, mutect2, varscan2
- RADIL | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV68199446; called by muse, mutect2, varscan2
- REG1B | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59304610; called by muse, mutect2, varscan2
- RFX3 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV56508676; called by muse, mutect2, varscan2
- RHCG | c.650C>A p.S217* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as rs749575034, COSV51514659, COSV51515857; called by muse, mutect2, varscan2
- SEMA3A | c.2198G>T p.R733L | Missense Mutation (SNP) | VAF 71/170 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.089); catalogued as CM127987, COSV54862815; called by muse, mutect2, varscan2
- SERPINC1 | c.1079G>A p.G360D | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.167); catalogued as rs1410177368, COSV62928923; called by mutect2, varscan2
- SLC26A7 | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV52599944; called by muse, mutect2, varscan2
- SPEF2 | c.19C>T p.Q7* | Nonsense Mutation (SNP) | VAF 13/109 reads (12%) | catalogued as COSV56795018; called by muse, mutect2, varscan2
- SPINK9 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 122/435 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64957866; called by muse, mutect2, varscan2
- SPTBN4 | c.1531G>C p.D511H | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as COSV58944234; called by muse, mutect2, varscan2
- TCP1 | c.427C>G p.L143V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.378); catalogued as COSV58457621; called by muse, varscan2
- TFAP2C | c.1166G>A p.C389Y | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs762413823, COSV52370554; called by mutect2, varscan2
- TIRAP | c.646+8A>G | Splice Region (SNP) | VAF 5/17 reads (29%) | catalogued as COSV67023836; called by muse, mutect2, varscan2
- TMC7 | c.1120G>T p.G374W | Missense Mutation (SNP) | VAF 74/142 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV58581763; called by muse, varscan2
- TMEM260 | c.1286C>G p.S429C | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55097317; called by muse, mutect2, varscan2
- TNKS1BP1 | c.1642C>G p.P548A | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV64100093; called by muse, varscan2
- TNKS1BP1 | c.1553C>T p.S518F | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV64100098; called by muse, varscan2
- TTC28 | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1254650178, COSV67414239; called by muse, mutect2, varscan2
- TTC3 | c.2998C>T p.R1000C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs757542457, COSV61286358, COSV61292440; called by muse, mutect2, varscan2
- TTC3 | c.4385A>G p.Q1462R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs1239369508, COSV61286373; called by muse, varscan2
- TUBB4B | c.998T>C p.V333A | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.134); catalogued as COSV61115599; called by muse, mutect2, varscan2
- USP25 | c.1289A>G p.Q430R | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV53481564; called by muse, mutect2, varscan2
- WBP2 | c.46A>G p.N16D | Missense Mutation (SNP) | VAF 88/96 reads (92%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as COSV54662952; called by muse, mutect2, varscan2
- XIRP2 | c.505G>T p.V169F (on ENST00000628543; = p.V344F on NM_152381.6) | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as COSV54684760; called by muse, mutect2, varscan2
- ZBTB6 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.867); catalogued as COSV65409491; called by muse, mutect2, varscan2
- ZNF671 | c.1024G>A p.E342K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.516); catalogued as rs750871699, COSV58051828; called by mutect2, varscan2
- ZNF827 | c.7A>T p.R3W | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV65225173; called by muse, mutect2, varscan2
- ADAMTS3 | c.2115_2117delinsA p.C705* | Nonsense Mutation (DEL) | VAF 3/30 reads (10%) | called by pindel, varscan2*
- ALB | c.1341dup p.V448Cfs*16 | Frame Shift Ins (INS) | VAF 36/60 reads (60%) | called by pindel, varscan2
- ALB | c.1428+2_1428+3del p.X476_splice | Splice Site (DEL) | VAF 16/27 reads (59%) | called by pindel, varscan2
- KIF3B | c.166del p.T56Pfs*90 | Frame Shift Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- L3MBTL1 | c.514del p.Q172Rfs*50 (on ENST00000418998 / NM_001377303.1; = p.Q82Rfs*50 on NM_015478.7) | Frame Shift Del (DEL) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- MAP2K2 | c.974_981dup p.E328Lfs*2 | Nonsense Mutation (INS) | VAF 14/20 reads (70%) | called by mutect2, varscan2
- SULT2A1 | c.736_745+10del p.X246_splice | Splice Site (DEL) | VAF 10/76 reads (13%) | called by pindel, varscan2
- TTLL3 | c.1590_1591del p.N531Lfs*16 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by pindel, varscan2
- ATCAY | c.162C>T p.N54= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs373392142; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CR2 | c.480C>T p.I160= | Silent (SNP) | VAF 150/268 reads (56%) | catalogued as COSV65506208; called by muse, mutect2, varscan2
- EWSR1 | c.1363C>A p.R455= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs772636858, COSV100132071, COSV58421516; called by mutect2, varscan2
- GRXCR1 | c.348C>T p.G116= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs778007626, COSV67670293; called by muse, mutect2, varscan2
- HTR1B | c.711C>T p.S237= | Silent (SNP) | VAF 18/22 reads (82%) | catalogued as COSV64051137; called by muse, mutect2, varscan2
- LAMA5 | c.9861T>C p.N3287= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as rs759422371, COSV53353679; called by muse, mutect2, varscan2
- NFYC | c.192A>G p.E64= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs756363774, COSV58125870; called by muse, varscan2
- OR8B8 | c.639C>A p.T213= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as COSV60143890; called by muse, mutect2, varscan2
- OSBPL10 | c.2205C>T p.R735= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs1419362955, COSV67336634; called by muse, mutect2, varscan2
- PADI1 | c.1395G>A p.S465= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as rs766287642, COSV64937828; called by muse, mutect2, varscan2
- PRR16 | c.744C>T p.G248= (on ENST00000407149 / NM_001300783.2; = p.G225= on NM_016644.2) | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as rs1199871647, COSV65395188; called by muse, mutect2, varscan2
- REPS2 | c.1506C>T p.P502= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV58179394; called by muse, mutect2, varscan2
- RNF123 | c.3384G>C p.L1128= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV57537651; called by muse, mutect2, varscan2
- SEMA4F | c.960G>C p.G320= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV60282044; called by muse, mutect2
- TACR2 | c.201C>T p.V67= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV64821899; called by muse, mutect2, varscan2
- TMPRSS7 | c.681G>A p.V227= (on ENST00000452346; = p.V114= on NM_001042575.2) | Silent (SNP) | VAF 113/293 reads (39%) | catalogued as COSV69979683; called by muse, mutect2, varscan2
- TRIM44 | c.84G>T p.G28= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as COSV54982453; called by muse, mutect2, varscan2
- TUBGCP2 | c.1818G>T p.T606= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV53303246; called by muse, mutect2, varscan2
- YES1 | c.984A>G p.R328= | Silent (SNP) | VAF 64/123 reads (52%) | catalogued as rs1209775122, COSV58848263; called by muse, mutect2, varscan2
- YOD1 | c.270C>T p.L90= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV60005940; called by muse, mutect2
- ZNF131 | c.969T>C p.T323= (on ENST00000509156 / NM_001330707.2; = p.T289= on NM_003432.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 69/129 reads (53%) | catalogued as COSV61001331; called by muse, mutect2, varscan2
- ZNF831 | c.949C>A p.R317= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV64037778, COSV64042613; called by muse, mutect2
- ZSWIM8 | c.234G>A p.E78= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV67131241; called by mutect2, varscan2
- ADAP1 | c.306-750G>A | Intron (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- B3GNT5 | c.*1050A>T | 3'UTR (SNP) | VAF 32/190 reads (17%) | catalogued as COSV100193934; called by muse, mutect2, varscan2
- CDH13 | c.*24A>G | 3'UTR (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99230886; called by mutect2, varscan2
- GRIA4 | c.1269+1368G>T | Intron (SNP) | VAF 28/69 reads (41%) | catalogued as COSV99234436; called by muse, mutect2, varscan2
- PCGF3 | c.109+374G>A | Intron (SNP) | VAF 28/69 reads (41%) | catalogued as rs953646797, COSV100745463; called by muse, mutect2, varscan2
- PCNX4 | c.689+2005A>C | Intron (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
